Somatic mutation profile of tumor specimen TCGA-16-0846-01A (aliquot TCGA-16-0846-01A-01D-1492-08) from TCGA case TCGA-16-0846, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 85.2 years (31,111 days).
Specimen TCGA-16-0846-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd38bc6b-723a-4368-afec-8070ee863432.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-16-0846-10A (Blood Derived Normal), aliquot TCGA-16-0846-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ddb96f5-835f-4653-be32-7272a248e00a

The open-access MAF lists 77 somatic variants for this specimen: 54 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 20, Nonsense Mutation 2, 3'UTR 1, Splice Site 1, Intron 1, Frame Shift Ins 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 43/75 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAT3 | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.236); catalogued as COSV60190518; called by muse, mutect2, varscan2
- AEBP1 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.04); catalogued as rs769957543, COSV56256355; called by muse, mutect2
- BIN2 | c.217+1G>A p.X73_splice | Splice Site (SNP) | VAF 63/187 reads (34%) | catalogued as COSV57204516; called by muse, mutect2, varscan2
- C9 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV54675347; called by muse, mutect2, varscan2
- CD38 | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV56889076; called by muse, mutect2
- COL3A1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.328); catalogued as rs187907868, COSV58584690, COSV58597018; called by muse, mutect2, varscan2
- CPA4 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs751553332, COSV55982374, COSV55982540; called by muse, mutect2, varscan2
- DMD | c.4170C>G p.D1390E | Missense Mutation (SNP) | VAF 44/55 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs886043687, COSV63742989; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM124A | c.202G>A p.V68I (on ENST00000322475 / NM_001242312.2; = p.V104I on NM_145019.4) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.654); catalogued as rs1433534038, COSV54475053; called by muse, mutect2, varscan2
- FOXA1 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.539); catalogued as COSV51644795; called by muse, mutect2, varscan2
- GIMAP7 | c.34G>A p.V12I | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.271); catalogued as rs748612836, COSV57958762; called by muse, mutect2, varscan2
- GRM7 | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63136158; called by muse, mutect2, varscan2
- HOXD4 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV60459549; called by muse, mutect2, varscan2
- IL4R | c.500A>T p.N167I | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.215); catalogued as COSV50139988; called by muse, mutect2, varscan2
- LRRC30 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as COSV67301504; called by muse, mutect2, varscan2
- MAPK15 | c.562G>T p.V188L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV62027786; called by muse, mutect2, varscan2
- MFSD2A | c.895C>T p.R299W (on ENST00000372809 / NM_001136493.3; = p.R286W on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.117); catalogued as rs373419262; called by muse, mutect2, varscan2
- MIB1 | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.863); catalogued as COSV55088873; called by muse, mutect2
- MUC17 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as rs777479634, COSV60283635; called by muse, mutect2, varscan2
- MYO7B | c.3280C>T p.H1094Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV67345917; called by muse, mutect2, varscan2
- MYO9B | c.4577G>A p.R1526H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.388); catalogued as rs1393589546, COSV68277931, COSV68281842; called by muse, varscan2
- NAV2 | c.2174A>G p.H725R (on ENST00000396087 / NM_001244963.2; = p.H702R on NM_145117.5) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.034); catalogued as rs768598584, COSV62318643; called by muse, mutect2
- OLFML2B | c.439C>T p.L147F | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV54195095; called by muse, mutect2, varscan2
- OR10H5 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV58277714; called by muse, mutect2, varscan2
- OR51A4 | c.410T>C p.I137T | Missense Mutation (SNP) | VAF 160/519 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV66749216; called by muse, mutect2, varscan2
- OR6C75 | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58551679; called by muse, mutect2, varscan2
- PCDH11X | c.2287T>A p.F763I | Missense Mutation (SNP) | VAF 69/99 reads (70%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.698); catalogued as COSV53452590; called by muse, mutect2, varscan2
- PRKDC | c.6124C>T p.Q2042* | Nonsense Mutation (SNP) | VAF 33/140 reads (24%) | catalogued as COSV58047529, COSV58067452; called by muse, mutect2, varscan2
- PTEN | c.253G>T p.V85F | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64293021, COSV64299567; called by muse, mutect2, varscan2
- PUS7 | c.1363T>G p.Y455D | Missense Mutation (SNP) | VAF 70/261 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.659); catalogued as COSV62676270; called by muse, mutect2, varscan2
- RP1 | c.4490A>T p.E1497V | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV55113053; called by muse, mutect2, varscan2
- S1PR2 | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100495323; called by muse, varscan2
- SALL3 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.263); catalogued as rs1230527569, COSV73305888; called by muse, mutect2, varscan2
- SCN9A | c.4903T>A p.F1635I (on ENST00000303354; = p.F1624I on NM_002977.3) | Missense Mutation (SNP) | VAF 124/234 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57604428, COSV57620670; called by muse, mutect2, varscan2
- SEC23IP | c.1177A>G p.M393V | Missense Mutation (SNP) | VAF 57/75 reads (76%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV64831075; called by muse, mutect2, varscan2
- SEL1L2 | c.1842G>T p.L614F | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.525); catalogued as COSV53149709; called by muse, mutect2, varscan2
- SERPING1 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as rs867177349, COSV99557995; called by muse, mutect2, varscan2
- SMC1B | c.2870C>T p.T957I | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.337); catalogued as COSV62528915; called by muse, mutect2, varscan2
- SRMS | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99420575; called by muse, mutect2, varscan2
- TBX5 | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV59859397; called by muse, mutect2, varscan2
- TM2D1 | c.88A>T p.T30S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV53905823; called by muse, mutect2, varscan2
- TRIM51 | c.591C>A p.H197Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV55265016; called by muse, mutect2, varscan2
- TRPA1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV51557794; called by muse, mutect2, varscan2
- TSHZ3 | c.1014_1015insA p.G339Rfs*26 | Frame Shift Ins (INS) | VAF 31/277 reads (11%) | catalogued as COSV99551716; called by mutect2, pindel, varscan2
- UNC13C | c.3475G>A p.G1159S | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52854602; called by muse, mutect2, varscan2
- VDAC2 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV53685458; called by muse, mutect2, varscan2
- YY1AP1 | c.1868T>A p.V623D (on ENST00000295566 / NM_139118.2; = p.V566D on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as rs760889972, COSV55119929; called by muse, mutect2, varscan2
- ZBP1 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV59060911; called by muse, mutect2, varscan2
- ZNF319 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.914); catalogued as rs1184321445, COSV54621597; called by muse, mutect2, varscan2
- ZNF680 | c.239T>C p.V80A | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV59014571; called by muse, mutect2, varscan2
- ZNF776 | c.1273G>T p.V425F | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57814800; called by muse, mutect2
- MRC1 | c.1257T>G p.N419K | Missense Mutation (SNP) | VAF 27/600 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.174); called by muse, mutect2
- ZFP28 | c.780del p.N260Kfs*17 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by mutect2, pindel
- C1QTNF6 | c.759C>T p.R253= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs778601751, COSV55396006; called by muse, mutect2, varscan2
- CPVL | c.102A>G p.P34= | Silent (SNP) | VAF 48/140 reads (34%) | catalogued as COSV55300603; called by muse, mutect2, varscan2
- FAM151A | c.591C>A p.V197= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as COSV56363422, COSV56366793; called by muse, mutect2, varscan2
- FAM71E1 | c.27C>T p.L9= | Silent (SNP) | VAF 9/114 reads (8%) | catalogued as COSV58541952; called by muse, mutect2
- FGD6 | c.879A>G p.S293= | Silent (SNP) | VAF 75/188 reads (40%) | catalogued as rs1317708670, COSV59691547; called by muse, mutect2, varscan2
- GABRE | c.975C>A p.T325= | Silent (SNP) | VAF 26/36 reads (72%) | catalogued as rs483352728, COSV64819196; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GALNT7 | c.1026C>T p.P342= | Silent (SNP) | VAF 52/99 reads (53%) | catalogued as COSV53928056; called by muse, mutect2, varscan2
- HYDIN | c.9939C>T p.A3313= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs553587582, COSV66863115; called by muse, mutect2, varscan2
- ILF3 | c.1701A>G p.Q567= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV51555305; called by muse, mutect2, varscan2
- INTS9 | c.1680C>A p.A560= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as COSV68433577; called by muse, mutect2, varscan2
- KIAA0319 | c.2550G>A p.S850= | Silent (SNP) | VAF 43/78 reads (55%) | catalogued as rs890623665, COSV65497245; called by muse, mutect2, varscan2
- LAMB3 | c.2058C>T p.D686= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as COSV61915891; called by muse, mutect2
- MYOCD | c.1458G>A p.P486= | Silent (SNP) | VAF 29/54 reads (54%) | catalogued as rs781734613, COSV58500177; called by muse, mutect2, varscan2
- PRKAG3 | c.1263G>A p.L421= | Silent (SNP) | VAF 41/82 reads (50%) | catalogued as COSV52101267; called by muse, mutect2, varscan2
- RELN | c.10101C>T p.N3367= | Silent (SNP) | VAF 32/310 reads (10%) | catalogued as rs757164573, COSV58992591; ClinVar: likely benign; called by muse, mutect2
- SERPINB11 | c.96G>A p.S32= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs758965113, COSV66956621; called by muse, mutect2, varscan2
- SLC28A1 | c.654A>T p.G218= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs760883725, COSV54477567; called by muse, mutect2, varscan2
- TH | c.1221C>T p.F407= (on ENST00000381178 / NM_199292.3; = p.F376= on NM_000360.4) | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs769329337, COSV51746760; ClinVar: likely benign; called by mutect2, varscan2
- TRBC2 | c.147G>A p.G49= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs1554512572; called by muse, mutect2, varscan2
- Z83844.2 | c.1188G>A p.A396= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs746933688, COSV60927392; called by muse, mutect2, varscan2
- MIR498 | n.49C>T | RNA (SNP) | VAF 90/201 reads (45%) | catalogued as rs750516141; called by muse, mutect2, varscan2
- POLR3G | c.*120G>A | 3'UTR (SNP) | VAF 37/92 reads (40%) | catalogued as rs375576885; called by muse, mutect2, varscan2
- TM9SF1 | c.1427+39C>G | Intron (SNP) | VAF 48/107 reads (45%) | catalogued as COSV55779058, COSV55779630, COSV99938056; called by muse, mutect2, varscan2
